Somatic mutation profile of tumor specimen 0DHFP3 from CCDI case PBBUIL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 1.3 years (485 days).
Specimen 0DHFP3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5ee1ba9-4c4c-4bc9-814d-8ffd65e9c216.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHFL0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45593c45-71a4-49c9-9813-be6928f14943

The open-access MAF lists 150 somatic variants for this specimen: 50 protein-altering or splice-affecting, 13 silent, 87 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 51, Missense Mutation 40, 3'UTR 19, Silent 13, 5'UTR 12, Nonsense Mutation 6, RNA 3, Splice Region 2, Splice Site 2, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.1987G>C p.V663L | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.444); catalogued as COSV57662870; called by muse, varscan2
- ANKRD20A4P | c.2088A>T p.Q696H | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs75696372; called by muse, varscan2
- ARHGEF10L | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs1414327313; called by muse, varscan2
- BAZ1B | c.1046C>A p.S349* | Nonsense Mutation (SNP) | VAF 103/530 reads (19%) | catalogued as COSV59989381; called by muse, varscan2
- BDP1 | c.490-1G>T p.X164_splice | Splice Site (SNP) | VAF 55/545 reads (10%) | catalogued as COSV62431386; called by muse, varscan2
- CDC27 | c.761T>G p.L254* | Nonsense Mutation (SNP) | VAF 89/926 reads (10%) | catalogued as rs62077264, COSV50369891; called by muse, varscan2
- CLDN14 | c.555C>G p.C185W | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV59772060; called by muse, varscan2
- GOLGA6C | c.539C>A p.S180Y | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1456097451; called by muse, varscan2
- HNRNPF | c.1167C>A p.Y389* | Nonsense Mutation (SNP) | VAF 62/476 reads (13%) | catalogued as rs375590998, COSV100563101, COSV61561063; called by muse, varscan2
- HNRNPF | c.1166A>T p.Y389F | Missense Mutation (SNP) | VAF 60/472 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1222613734, COSV100563103; called by muse, varscan2
- HNRNPF | c.1165T>G p.Y389D | Missense Mutation (SNP) | VAF 60/472 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs1350872727, COSV100563104; called by muse, varscan2
- IL2RB | c.1336G>A p.G446R | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.967); catalogued as rs1487017993; called by muse, varscan2
- MBD5 | c.801C>G p.H267Q | Missense Mutation (SNP) | VAF 49/439 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs747135508; ClinVar: uncertain significance; called by muse, varscan2
- MPHOSPH9 | c.1622C>T p.T541I | Missense Mutation (SNP) | VAF 84/686 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs774004386; called by muse, varscan2
- RASGRF2 | c.922C>G p.Q308E | Missense Mutation (SNP) | VAF 74/678 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99429135; called by muse, varscan2
- SEC14L5 | c.1677G>C p.R559S | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV99229163; called by muse, varscan2
- TFDP3 | c.390C>G p.C130W | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs772108089; called by muse, varscan2
- TTC30B | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 80/476 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs368765664; called by muse, varscan2
- BAZ1B | c.1045T>G p.S349A | Missense Mutation (SNP) | VAF 106/530 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.014); called by muse, varscan2
- C1QB | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.043); called by muse, varscan2
- C1QB | c.578T>C p.V193A | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.05); called by muse, varscan2
- CCDC168 | c.4588C>T p.Q1530* | Nonsense Mutation (SNP) | VAF 94/524 reads (18%) | called by muse, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 138/866 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, varscan2
- CDV3 | c.627-3T>A | Splice Region (SNP) | VAF 78/364 reads (21%) | called by muse, varscan2
- CEP120 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 64/476 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, varscan2
- CHGA | c.1204A>G p.S402G | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, varscan2
- COL7A1 | c.5776C>G p.L1926V | Missense Mutation (SNP) | VAF 58/290 reads (20%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.975); called by muse, varscan2
- COL7A1 | c.5775C>A p.G1925= | Splice Region (SNP) | VAF 58/286 reads (20%) | called by muse, varscan2
- DHX29 | c.2666A>T p.N889I | Missense Mutation (SNP) | VAF 93/832 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, varscan2
- ENDOD1 | c.865A>T p.I289F | Missense Mutation (SNP) | VAF 94/792 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, varscan2
- EPRS1 | c.2553T>A p.N851K | Missense Mutation (SNP) | VAF 80/713 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, varscan2
- EPRS1 | c.2542G>C p.A848P | Missense Mutation (SNP) | VAF 151/622 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.633); called by muse, varscan2
- GLO1 | c.467-2A>C p.X156_splice | Splice Site (SNP) | VAF 85/468 reads (18%) | called by muse, varscan2
- GOLGA6D | c.539C>A p.S180Y | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, varscan2
- KCNJ12 | c.548A>T p.K183M | Missense Mutation (SNP) | VAF 64/322 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KCNJ18 | c.548A>T p.K183M | Missense Mutation (SNP) | VAF 66/310 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MBD5 | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 49/437 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, varscan2
- MPHOSPH9 | c.2652A>G p.I884M | Missense Mutation (SNP) | VAF 121/977 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.06); called by muse, varscan2
- NPAT | c.1729A>T p.K577* | Nonsense Mutation (SNP) | VAF 77/602 reads (13%) | called by muse, varscan2
- NRAP | c.1843G>C p.V615L (on ENST00000359988 / NM_001322945.2; = p.V580L on NM_006175.4) | Missense Mutation (SNP) | VAF 66/266 reads (25%) | SIFT tolerated (0.99); PolyPhen benign (0.115); called by muse, varscan2
- NUP93 | c.41A>T p.E14V | Missense Mutation (SNP) | VAF 71/454 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); called by muse, varscan2
- NUP93 | c.42A>T p.E14D | Missense Mutation (SNP) | VAF 71/452 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.275); called by muse, varscan2
- OR1N2 | c.516T>G p.C172W | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PLXNB3 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); called by muse, varscan2
- PPP4R3A | c.521T>A p.L174Q | Missense Mutation (SNP) | VAF 146/717 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- RPA4 | c.445G>T p.E149* | Nonsense Mutation (SNP) | VAF 16/142 reads (11%) | called by muse, varscan2
- THADA | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 106/811 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, varscan2
- UTY | c.2804C>T p.T935I | Missense Mutation (SNP) | VAF 60/282 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- XRN1 | c.3680C>G p.T1227S | Missense Mutation (SNP) | VAF 74/575 reads (13%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 92/878 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, varscan2
- ACRBP | c.15C>G p.A5= | Silent (SNP) | VAF 42/202 reads (21%) | catalogued as rs143135414; called by muse, varscan2
- AWAT1 | c.306T>G p.V102= | Silent (SNP) | VAF 24/203 reads (12%) | called by muse, varscan2
- BEST4 | c.918T>A p.A306= | Silent (SNP) | VAF 14/100 reads (14%) | called by muse, varscan2
- CD180 | c.681G>A p.L227= | Silent (SNP) | VAF 113/555 reads (20%) | catalogued as rs1192077978, COSV56518622; called by muse, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 42/254 reads (17%) | catalogued as rs1167537044; called by muse, varscan2
- CHGA | c.1203C>T p.D401= | Silent (SNP) | VAF 20/156 reads (13%) | called by muse, varscan2
- OR1N1 | c.816A>T p.A272= | Silent (SNP) | VAF 40/218 reads (18%) | called by muse, varscan2
- RBM19 | c.672G>C p.S224= | Silent (SNP) | VAF 70/444 reads (16%) | called by muse, varscan2
- RPL4 | c.444T>G p.P148= | Silent (SNP) | VAF 58/515 reads (11%) | called by muse, varscan2
- TTC30B | c.621A>G p.A207= | Silent (SNP) | VAF 81/480 reads (17%) | catalogued as rs750265989; called by muse, varscan2
- TTN | c.80505A>G p.Q26835= (on ENST00000591111; = p.Q19411= on NM_003319.4) | Silent (SNP) | VAF 78/502 reads (16%) | catalogued as rs777939514, COSV100605900; ClinVar: uncertain significance; called by muse, varscan2
- TTN | c.80490C>T p.S26830= (on ENST00000591111; = p.S19406= on NM_003319.4) | Silent (SNP) | VAF 65/405 reads (16%) | called by muse, varscan2
- XRN1 | c.3681T>C p.T1227= | Silent (SNP) | VAF 74/582 reads (13%) | catalogued as rs760662330; called by muse, varscan2
- ABCA3 | c.613+94G>C | Intron (SNP) | VAF 9/54 reads (17%) | catalogued as rs1262556378; called by muse, varscan2
- ADAM8 | c.1107-25C>A | Intron (SNP) | VAF 32/141 reads (23%) | catalogued as rs1025095610; called by muse, varscan2
- ANGPTL4 | c.*19T>G | 3'UTR (SNP) | VAF 14/106 reads (13%) | called by muse, varscan2
- ANGPTL4 | c.*20C>A | 3'UTR (SNP) | VAF 14/106 reads (13%) | called by muse, varscan2
- APOC4 | c.*56A>G | 3'UTR (SNP) | VAF 30/309 reads (10%) | called by muse, varscan2
- APOE | c.-34C>A | 5'UTR (SNP) | VAF 10/82 reads (12%) | catalogued as COSV52986515; called by muse, varscan2
- ARHGEF12 | c.3532+91T>C | Intron (SNP) | VAF 32/180 reads (18%) | called by muse, varscan2
- ARHGEF12 | c.3532+92G>A | Intron (SNP) | VAF 34/176 reads (19%) | called by muse, varscan2
- ARL4C | c.*65T>A | 3'UTR (SNP) | VAF 9/80 reads (11%) | catalogued as rs949105807, COSV100327080; called by muse, varscan2
- B4GALT2 | c.968+85A>G | Intron (SNP) | VAF 6/44 reads (14%) | called by muse, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 111/656 reads (17%) | called by muse, varscan2
- C3orf49 | c.849+99T>C | Intron (SNP) | VAF 12/64 reads (19%) | called by muse, varscan2
- CACNB4 | c.*95T>A | 3'UTR (SNP) | VAF 22/94 reads (23%) | called by muse, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 38/188 reads (20%) | called by muse, varscan2
- CALCOCO2 | c.825+77T>A | Intron (SNP) | VAF 38/183 reads (21%) | called by muse, varscan2
- CCDC88B | c.676-94C>T | Intron (SNP) | VAF 18/82 reads (22%) | catalogued as rs778974800; called by muse, varscan2
- CEP290 | c.495+46A>T | Intron (SNP) | VAF 51/458 reads (11%) | called by muse, varscan2
- CEP43 | c.301-88G>A | Intron (SNP) | VAF 18/132 reads (14%) | called by muse, varscan2
- COMP | c.1136-76C>G | Intron (SNP) | VAF 15/140 reads (11%) | catalogued as rs866516146; called by muse, varscan2
- CRB1 | c.2677-473G>A | Intron (SNP) | VAF 35/258 reads (14%) | called by muse, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 142/625 reads (23%) | called by muse, varscan2
- CYP21A2 | c.292+38T>A | Intron (SNP) | VAF 64/361 reads (18%) | catalogued as rs1288475272; called by muse, varscan2
- DENND2C | c.2755+70T>C | Intron (SNP) | VAF 28/166 reads (17%) | called by muse, varscan2
- DHX16 | c.*60C>G | 3'UTR (SNP) | VAF 42/248 reads (17%) | called by muse, varscan2
- ERCC6L2 | c.471+29C>G | Intron (SNP) | VAF 52/476 reads (11%) | called by muse, varscan2
- FAM3B | c.397+29A>T | Intron (SNP) | VAF 68/350 reads (19%) | called by muse, varscan2
- FAM3B | c.397+30A>T | Intron (SNP) | VAF 68/348 reads (20%) | called by muse, varscan2
- FCHO2 | c.1173+13A>G | Intron (SNP) | VAF 35/324 reads (11%) | called by muse, varscan2
- FGFR1OP2 | c.396+73T>C | Intron (SNP) | VAF 12/93 reads (13%) | catalogued as COSV99987084; called by muse, varscan2
- FRAS1 | c.5856+113A>T | Intron (SNP) | VAF 28/178 reads (16%) | called by muse, varscan2
- FRYL | c.8395-82T>G | Intron (SNP) | VAF 49/311 reads (16%) | called by muse, varscan2
- GALR2 | c.-1C>G | 5'UTR (SNP) | VAF 20/121 reads (17%) | called by muse, varscan2
- GGA1 | c.44-53A>G | Intron (SNP) | VAF 10/57 reads (18%) | called by muse, varscan2
- GLCCI1 | c.696+91A>G | Intron (SNP) | VAF 20/125 reads (16%) | called by muse, varscan2
- GOLIM4 | c.600+64A>T | Intron (SNP) | VAF 39/343 reads (11%) | called by muse, varscan2
- GPRC5B | chr16:19885643 C>T | 5'Flank (SNP) | VAF 6/30 reads (20%) | called by muse, varscan2
- GTF2A1 | c.*23A>T | 3'UTR (SNP) | VAF 44/340 reads (13%) | called by muse, varscan2
- HERC1 | c.13689-37G>T | Intron (SNP) | VAF 12/116 reads (10%) | called by muse, varscan2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 18/93 reads (19%) | called by muse, varscan2
- HEXIM1 | c.*69T>C | 3'UTR (SNP) | VAF 7/46 reads (15%) | called by muse, varscan2
- ITGB1 | c.2331+1162A>G | Intron (SNP) | VAF 27/125 reads (22%) | catalogued as rs560657508; called by muse, varscan2
- ITGB1 | c.2331+1161C>T | Intron (SNP) | VAF 26/120 reads (22%) | catalogued as rs527739481; called by muse, varscan2
- KCNK10 | c.38-7275A>C | Intron (SNP) | VAF 42/184 reads (23%) | called by muse, varscan2
- KCNK10 | c.38-7279T>G | Intron (SNP) | VAF 45/170 reads (26%) | catalogued as rs376872265; called by muse, varscan2
- KCNK10 | c.38-7280C>T | Intron (SNP) | VAF 45/168 reads (27%) | called by muse, varscan2
- LARP4 | c.1334+88A>C | Intron (SNP) | VAF 16/94 reads (17%) | called by muse, varscan2
- LARP4 | c.1334+89G>T | Intron (SNP) | VAF 16/94 reads (17%) | called by muse, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 70/200 reads (35%) | called by muse, varscan2
- LINC02694 | n.552G>A | RNA (SNP) | VAF 70/196 reads (36%) | catalogued as rs768118261; called by muse, varscan2
- LPCAT2 | c.853-38T>C | Intron (SNP) | VAF 90/416 reads (22%) | called by muse, varscan2
- LRRC49 | c.-75C>T | 5'UTR (SNP) | VAF 16/126 reads (13%) | catalogued as rs916279605, COSV73410668; called by muse, varscan2
- LRRC63 | c.*79T>G | 3'UTR (SNP) | VAF 12/68 reads (18%) | called by muse, varscan2
- MCM2 | c.-41C>G | 5'UTR (SNP) | VAF 22/142 reads (15%) | called by muse, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 21/71 reads (30%) | called by muse, varscan2
- MED23 | c.2779-34G>T | Intron (SNP) | VAF 42/312 reads (13%) | called by muse, varscan2
- MTRNR2L8 | c.-8T>C | 5'UTR (SNP) | VAF 130/886 reads (15%) | catalogued as rs7350541, COSV56417119; called by muse, varscan2
- MYCBPAP | c.-8G>C | 5'UTR (SNP) | VAF 45/139 reads (32%) | called by muse, varscan2
- NCAPH2 | c.861+113C>G | Intron (SNP) | VAF 10/42 reads (24%) | catalogued as rs998143555; called by muse, varscan2
- NEBL | c.2055+52T>A | Intron (SNP) | VAF 20/194 reads (10%) | called by muse, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 16/112 reads (14%) | called by muse, varscan2
- NPAP1L | n.527C>T | RNA (SNP) | VAF 24/376 reads (6%) | catalogued as COSV73747612; called by muse, varscan2
- NR4A3 | c.*72G>C | 3'UTR (SNP) | VAF 10/58 reads (17%) | called by muse, varscan2
- NRCAM | c.-57C>A | 5'UTR (SNP) | VAF 83/282 reads (29%) | catalogued as rs926414386, COSV100695372; called by muse, varscan2
- NRCAM | c.-58T>G | 5'UTR (SNP) | VAF 83/268 reads (31%) | called by muse, varscan2
- NSMAF | c.2446+56A>T | Intron (SNP) | VAF 31/190 reads (16%) | called by muse, varscan2
- OR5V1 | c.*5C>G | 3'UTR (SNP) | VAF 45/361 reads (12%) | called by muse, varscan2
- ORC1 | c.*71G>A | 3'UTR (SNP) | VAF 23/198 reads (12%) | catalogued as rs1193824487, COSV65363475; called by muse, varscan2
- PATL2 | c.1464-32T>G | Intron (SNP) | VAF 32/162 reads (20%) | called by muse, varscan2
- PRPF3 | c.1283-42G>A | Intron (SNP) | VAF 16/146 reads (11%) | catalogued as rs1356369436; called by muse, varscan2
- PRPSAP2 | c.*9T>A | 3'UTR (SNP) | VAF 32/252 reads (13%) | called by muse, varscan2
- PSME3IP1 | c.*56C>A | 3'UTR (SNP) | VAF 12/112 reads (11%) | called by muse, varscan2
- RAB11FIP3 | c.1301+67A>G | Intron (SNP) | VAF 22/145 reads (15%) | catalogued as rs906756419; called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 92/296 reads (31%) | called by muse, varscan2
- SBSPON | c.*19C>A | 3'UTR (SNP) | VAF 52/391 reads (13%) | called by muse, varscan2
- SKIDA1 | c.-60G>A | 5'UTR (SNP) | VAF 30/179 reads (17%) | called by muse, varscan2
- SKIDA1 | c.-61T>C | 5'UTR (SNP) | VAF 29/175 reads (17%) | catalogued as rs1015442172; called by muse, varscan2
- SLCO2A1 | chr3:133928868 A>G | 3'Flank (SNP) | VAF 8/56 reads (14%) | called by muse, varscan2
- SON | c.6657+181A>T | Intron (SNP) | VAF 82/722 reads (11%) | called by muse, varscan2
- SVIP | c.54+424A>T | Intron (SNP) | VAF 42/371 reads (11%) | called by muse, varscan2
- TATDN1 | c.138+54T>A | Intron (SNP) | VAF 70/292 reads (24%) | called by muse, varscan2
- TDO2 | c.*89T>C | 3'UTR (SNP) | VAF 14/108 reads (13%) | catalogued as rs573370490; called by muse, varscan2
- TKFC | c.865+39G>C | Intron (SNP) | VAF 14/136 reads (10%) | called by muse, varscan2
- TRPA1 | c.1195-74T>A | Intron (SNP) | VAF 18/100 reads (18%) | called by muse, varscan2
- UQCRHL | c.-72A>G | 5'UTR (SNP) | VAF 20/184 reads (11%) | catalogued as rs897616552; called by muse, varscan2
- ZFP69B | c.*90T>A | 3'UTR (SNP) | VAF 20/203 reads (10%) | called by muse, varscan2
- ZFYVE16 | c.3607+79C>T | Intron (SNP) | VAF 16/93 reads (17%) | called by muse, varscan2
- ZNF277 | c.801+32A>T | Intron (SNP) | VAF 42/436 reads (10%) | called by muse, varscan2
